Gene-level copy-number profile of tumor specimen TCGA-55-7574-01A from TCGA case TCGA-55-7574, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.9 years (23,703 days).
Specimen TCGA-55-7574-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1dfa2ef7-892d-424a-8459-7837362b2b02.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7574-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32da8077-9f7e-42a3-b1b1-038813162407

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 16,283; copy number 2: 40,002; copy number 3: 1,593; copy number 4: 1,730; copy number 5: 114; copy number 6: 9; copy number 7: 87.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7574-01A-11D-2035-01): tumor purity 0.19, ploidy 2.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:35,752,814–35,753,719, 1 gene: RPF2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 210 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:212,852,105–218,918,714, 58 genes, copy number 5: FLVCR1-DT, AC104333.1, AC104333.2, FLVCR1, AC104333.4, VASH2, ANGEL2, RPS6KC1, RPL31P13, AL592402.1, AC096639.1, PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1, LINC02775, SMYD2, AL929236.1, PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG, GPATCH2, SPATA17, SPATA17-AS1, UBBP2, LINC00210, AL355526.1, LINC01653, AL355526.2, RNU1-141P, RRP15, AC096638.2, AC096638.1, TGFB2-AS1, TGFB2, TGFB2-OT1, LINC02869, U3, NXNP1, LINC01710.
- chr8:108,378,831–108,626,767, 4 genes, copy number 6: RPS17P14, EMC2, AC022634.1, AC022634.2.
- chr8:110,334,743–111,236,203, 9 genes, copy number 5 (within-gene range 3–5): AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1.
- chr8:115,950,511–116,403,757, 4 genes, copy number 6: LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr8:123,157,729–124,580,648, 47 genes, copy number 5: AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9.
- chr8:139,600,838–139,704,109, 1 gene, copy number 6 (within-gene range 3–6): KCNK9.
- chr20:34,194,569–35,742,312, 66 genes, copy number 7 (broad region; genes not listed).
- chr20:52,840,936–52,890,386, 3 genes, copy number 7: AL161945.1, AL121902.1, RPL36P1.
- chr20:53,097,652–53,141,169, 2 genes, copy number 7: RN7SKP184, AL391097.3.
- chr20:53,453,058–54,269,542, 16 genes, copy number 7: AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.

Autosomal genes at a single copy (total copy number 1): 14,999. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
